Somatic mutation profile of tumor specimen TCGA-N5-A4R8-01A (aliquot TCGA-N5-A4R8-01A-11D-A28R-08) from TCGA case TCGA-N5-A4R8, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IA; Age at diagnosis: 66.0 years (24,102 days).
Specimen TCGA-N5-A4R8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb57286e-8986-48bc-bf6a-73faabdf4222.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-N5-A4R8-10A (Blood Derived Normal), aliquot TCGA-N5-A4R8-10A-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/232655a6-7d77-4745-8eb8-d355063602db

The open-access MAF lists 56 somatic variants for this specimen: 49 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 41, Silent 7, Nonsense Mutation 4, In Frame Del 1, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 39/44 reads (89%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.560-2A>C p.X187_splice | Splice Site (SNP) | VAF 61/68 reads (90%) | hotspot (GDC flag); catalogued as CS150685, CS941545, COSV52664494, COSV52666095, COSV52685228; called by muse, mutect2, varscan2
- ABHD16A | c.137C>G p.T46R | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.046); catalogued as rs551585963; called by muse, mutect2, varscan2
- AC231657.3 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV59877112; called by muse, mutect2, varscan2
- AJAP1 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as rs369972327; called by muse, varscan2
- DACH1 | c.979G>C p.A327P | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.935); catalogued as COSV100498970; called by muse, mutect2
- FLVCR2 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 89/93 reads (96%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs199824003, COSV53164302; called by muse, mutect2, varscan2
- HEPH | c.1856G>A p.R619Q (on ENST00000343002; = p.R352Q on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs778854861, COSV57961563; called by muse, mutect2, varscan2
- NFIB | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 33/40 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV66620793; called by muse, mutect2, varscan2
- NRAP | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 24/97 reads (25%) | catalogued as COSV63492855; called by muse, mutect2, varscan2
- NRK | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs202127779, COSV54603611; called by muse, mutect2, varscan2
- PSME3 | c.438G>C p.R146S | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as rs760540189; called by muse, mutect2, varscan2
- RNF182 | c.513G>T p.W171C | Missense Mutation (SNP) | VAF 54/207 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV70369230; called by muse, mutect2, varscan2
- SLC5A8 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.044); catalogued as rs200408412, COSV101610541; called by muse, mutect2, varscan2
- SLC7A3 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs774144802; called by muse, varscan2
- TIGD5 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as rs370572958; called by muse, varscan2
- USP10 | c.1921C>T p.R641C | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as rs377254205; called by muse, varscan2
- ZBTB7B | c.472C>T p.R158* (on ENST00000292176; = p.R192* on NM_001252406.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 33/159 reads (21%) | catalogued as rs1406995274, COSV52692803; called by muse, mutect2, varscan2
- AHNAK | c.8091G>T p.M2697I | Missense Mutation (SNP) | VAF 152/238 reads (64%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- AKAP3 | c.772G>T p.G258* | Nonsense Mutation (SNP) | VAF 33/226 reads (15%) | called by muse, mutect2, varscan2
- ASB5 | c.37C>A p.Q13K | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- ATE1 | c.1516_1531del p.G506Sfs*36 | Frame Shift Del (DEL) | VAF 13/59 reads (22%) | called by mutect2, pindel, varscan2
- CALR | c.13G>A p.V5M | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC30 | c.669A>C p.K223N (on ENST00000340612; = p.K180N on NM_001080850.3) | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT tolerated (0.29); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- CELSR2 | c.695_697del p.F232del | In Frame Del (DEL) | VAF 19/54 reads (35%) | called by pindel, varscan2
- CEP20 | c.86G>A p.R29Q | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CLIC1 | c.240T>G p.I80M | Missense Mutation (SNP) | VAF 103/159 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- DNAH2 | c.3892A>G p.R1298G | Missense Mutation (SNP) | VAF 127/219 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- EFNB3 | c.370C>G p.L124V | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- ENPEP | c.1474T>C p.W492R | Missense Mutation (SNP) | VAF 28/47 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- HHIP | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HIVEP3 | c.5443G>C p.V1815L | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HSPG2 | c.10579G>A p.G3527R | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IPO11 | c.20G>T p.S7I | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- IRS1 | c.2069C>A p.P690H | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.2); called by muse, varscan2
- KLRB1 | c.7C>A p.Q3K | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.96); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KRTAP3-1 | c.112C>A p.H38N | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LAMA5 | c.1837G>T p.G613* | Nonsense Mutation (SNP) | VAF 46/61 reads (75%) | called by muse, mutect2, varscan2
- NKAPL | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 55/84 reads (65%) | SIFT tolerated (0.06); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- PCDHA11 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 149/166 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PRAMEF8 | c.60C>A p.D20E | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- RAD9A | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.282); called by muse, mutect2
- RMDN1 | c.384dup p.A129Sfs*4 | Frame Shift Ins (INS) | VAF 21/65 reads (32%) | called by mutect2, pindel, varscan2
- SHPRH | c.3668T>C p.I1223T (on ENST00000275233 / NM_001042683.3; = p.I1227T on NM_173082.3) | Missense Mutation (SNP) | VAF 51/73 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TPSG1 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- TRMT2B | c.634T>C p.S212P | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZKSCAN1 | c.1050G>C p.K350N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ZMYM6 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- ZNF84 | c.484G>C p.D162H | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.792C>T p.S264= | Silent (SNP) | VAF 19/67 reads (28%) | called by muse, mutect2, varscan2
- GJA1 | c.828T>C p.A276= | Silent (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- MGAM | c.2166C>T p.Y722= | Silent (SNP) | VAF 97/147 reads (66%) | catalogued as COSV101527532; called by muse, mutect2, varscan2
- MYOM2 | c.1047C>T p.D349= | Silent (SNP) | VAF 55/83 reads (66%) | catalogued as rs144735881; called by muse, mutect2, varscan2
- PHACTR2 | c.1338C>T p.D446= | Silent (SNP) | VAF 26/49 reads (53%) | catalogued as COSV99991591; called by muse, mutect2, varscan2
- SGIP1 | c.1278C>T p.P426= | Silent (SNP) | VAF 171/347 reads (49%) | catalogued as rs771506497, COSV52766003, COSV52779097; called by muse, mutect2, varscan2
- SLC25A3 | c.114C>G p.G38= | Silent (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
